Surgical pathology report (de-identified scan), TCGA case TCGA-A6-6650, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-A6-6650-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

SURGICAL PATHOLOGY REPORT

SPECIMEN

Right colon, hemicolectomy.

CLINICAL NOTES

--

GROSS DESCRIPTION

The specimen is received unfixed labeled right hemicolectomy and consists of a right hemicolectomy specimen. The right colon measures 14.5 cm in length and up to 6 cm in diameter. There is an attached segment of ileum measuring 16 cm in length and 2.3 cm in diameter. There is a dilated attached vermiform appendix measuring 6.5 cm in length and up to 1.2 cm in diameter. There also are small bubble like structures on the serosal surface of the cecum resembling pneumatosis. There is a fungating mass that appears to originate in the area of the orifice of the appendix. It measures 4.3 x 3.5 cm and is 11 cm from the colonic margin of resection. Sections after fixation and clearing. A portion of the tumor is taken for research purposes.

Block summary: 1,2 margins of resection; 3,4 appendix; 5 origin of appendix; 6 serosal vesicles; 7-11 tumor; 12-19 lymph nodes.

[REDACTED]

MICROSCOPIC DESCRIPTION

Tumor type: Colonic adenocarcinoma

Tumor grade: 2

Tumor size: 4.3 cm

Distance to nearest margin: 11 cm

Level of penetration: Carcinoma invades through the muscularis

propria into pericolic soft tissue.

Margins of resection: Negative for malignancy

Vascular invasion: No definite vascular invasion seen

Host response: Moderate acute and chronic inflammation

Attached lymph nodes: There is no evidence of malignancy in

any of 19 lymph nodes.

Non-lymph node pericolic tumor: Absent

pTNM Stage: T3 N0

Other findings: Benign serosal mesothelial cysts.

Fibrous obliteration of the distal appendiceal lumen.

[page 2 of 2]
DIAGNOSIS

Colon, right, resection: Moderately differentiated colonic adenocarcinoma

Note: Carcinoma invades through the muscularis propria into pericolic soft tissue. There is no evidence of malignancy in any of 19 pericolic lymph nodes.

--- End Of Report ---

Source: NCI Genomic Data Commons file 105803dc-9934-42b8-b575-c7fea03202f4 (TCGA-A6-6650.A3BACC5B-1C12-44E2-99F6-80BAA8668283.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).